Somatic mutation profile of tumor specimen 0DDX69 from CCDI case PBBNXZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.7 years (2,807 days).
Specimen 0DDX69: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58ee28b6-ac5c-46bb-8600-8209d86f6491.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDX64 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b12cfd09-d2d5-4971-a8f4-2e08f9c426ac

The open-access MAF lists 3 somatic variants for this specimen: 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HES7 | c.171G>A p.E57= | Silent (SNP) | VAF 19/576 reads (3%) | catalogued as COSV100502894; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 31/1238 reads (3%) | called by muse, mutect2
- RPL12 | c.111+72C>T | Intron (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
